Somatic mutation profile of tumor specimen TARGET-10-PARPNM-04A (aliquot TARGET-10-PARPNM-04A-01D) from TARGET case TARGET-10-PARPNM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,941 days).
Specimen TARGET-10-PARPNM-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38ee9043-9d35-4bea-9888-c90390ca56a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPNM-10A (Blood Derived Normal), aliquot TARGET-10-PARPNM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eb08b54-8545-41cb-86db-27a3b21c992d

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IQCF2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs369854806; called by muse, mutect2
- SLC22A24 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 14/165 reads (8%) | catalogued as rs1310730794, COSV70301141, COSV70302700; called by muse, mutect2
- DTWD2 | c.468A>G p.E156= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- PI4KA | c.4443G>A p.L1481= | Silent (SNP) | VAF 18/181 reads (10%) | catalogued as COSV55413535; called by muse, mutect2
